Somatic mutation profile of tumor specimen TCGA-NC-A5HK-01A (aliquot TCGA-NC-A5HK-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 58.9 years (21,531 days).
Specimen TCGA-NC-A5HK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7550f91-c88f-476e-87cd-b1c57e5dd933.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HK-10A (Blood Derived Normal), aliquot TCGA-NC-A5HK-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c10bb471-ba34-4065-b2e8-da6fecc752a8

The open-access MAF lists 287 somatic variants for this specimen: 231 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 49, Nonsense Mutation 15, Frame Shift Del 5, Splice Site 4, RNA 4, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, Translation Start Site 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADSS1 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140614802, CM162065; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PSENEN | c.66del p.X22_splice | Splice Site (DEL) | VAF 24/51 reads (47%) | catalogued as rs1555738837; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as rs876660825, CM161004, COSV52664064, COSV52987047, COSV53313892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA8 | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99287084; called by muse, mutect2, varscan2
- ACTRT1 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.951); catalogued as COSV100947782; called by muse, mutect2, varscan2
- ADAM2 | c.1188G>T p.E396D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99696745; called by muse, mutect2, varscan2
- ADAMTSL3 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as COSV54444341; called by muse, mutect2, varscan2
- AKAP9 | c.10691A>G p.E3564G (on ENST00000359028; = p.E3540G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100663264; called by muse, mutect2
- ALPG | c.809C>G p.T270S | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99779515; called by muse, mutect2, varscan2
- AMBRA1 | c.3787G>C p.A1263P (on ENST00000458649 / NM_001367468.1; = p.A1173P on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100095536; called by muse, mutect2, varscan2
- AP5S1 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs765677394, COSV55694684, COSV99853335; called by muse, mutect2, varscan2
- APBB1IP | c.72G>A p.Q24= | Splice Region (SNP) | VAF 27/58 reads (47%) | catalogued as COSV100774511; called by muse, mutect2, varscan2
- ARHGAP21 | c.3338A>T p.D1113V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100256613, COSV100256760; called by muse, mutect2, varscan2
- ARHGEF11 | c.3380A>T p.E1127V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as COSV100169042; called by muse, mutect2, varscan2
- ARHGEF4 | c.1991A>T p.Q664L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV100388823; called by muse, mutect2, varscan2
- ARID1B | c.6705G>T p.Q2235H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV99272813; called by muse, mutect2, varscan2
- ARID4B | c.544A>T p.I182F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99936481; called by muse, mutect2, varscan2
- ASAH1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757410765, COSV100026018; called by muse, mutect2, varscan2
- ASAH2 | c.1585C>T p.L529F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs1041900205; called by muse, mutect2, varscan2
- ATG7 | c.288C>G p.F96L | Missense Mutation (SNP) | VAF 128/185 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100608102; called by muse, mutect2, varscan2
- ATP11A | c.2915G>T p.G972V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99370185; called by muse, mutect2, varscan2
- ATP11C | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558770; called by muse, mutect2, varscan2
- BEND6 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV66069169; called by muse, mutect2
- BEND6 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.067); catalogued as COSV100876987, COSV66070120; called by muse, mutect2
- BRD9 | c.982A>T p.R328W | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100057667; called by muse, mutect2, varscan2
- BRINP2 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs769674620, COSV100838518; called by muse, mutect2, varscan2
- C6 | c.1713G>T p.W571C | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667919; called by muse, mutect2, varscan2
- C6 | c.1712G>C p.W571S | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99667920; called by muse, mutect2, varscan2
- CCNYL1 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99776103; called by muse, mutect2, varscan2
- CD19 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs759262975, COSV100218293; called by muse, mutect2, varscan2
- CDH10 | c.2163T>G p.H721Q | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100053361; called by muse, mutect2, varscan2
- CDH10 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as rs544297913, COSV52569597; called by muse, mutect2, varscan2
- CDH12 | c.251A>T p.K84M | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV101203416; called by muse, mutect2, varscan2
- CDH15 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228363, COSV99228947; called by muse, mutect2, varscan2
- CERS2 | c.417A>T p.R139S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99646003; called by muse, mutect2
- CFAP47 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as COSV52886630; called by muse, mutect2, varscan2
- CFHR5 | c.1373G>C p.G458A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99889888; called by muse, mutect2
- CHI3L1 | c.25+1G>T p.X9_splice | Splice Site (SNP) | VAF 38/148 reads (26%) | catalogued as COSV99704190; called by muse, mutect2, varscan2
- CHST12 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV99324710; called by muse, mutect2, varscan2
- CNBD1 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101582333; called by muse, mutect2
- CNTNAP5 | c.2908G>T p.G970W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101444319; called by muse, mutect2, varscan2
- COL11A1 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100618208; called by muse, mutect2, varscan2
- COL19A1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100507667; called by muse, mutect2, varscan2
- COL6A3 | c.7879G>T p.A2627S | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.314); catalogued as COSV99802030; called by muse, mutect2, varscan2
- CPN1 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100962756; called by muse, mutect2, varscan2
- CPS1 | c.1987T>G p.S663A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99244335; called by muse, mutect2, varscan2
- CWH43 | c.1742A>T p.Y581F | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99894264; called by muse, mutect2, varscan2
- DAND5 | c.496A>G p.S166G | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100397332; called by muse, mutect2, varscan2
- DDHD1 | c.208G>T p.E70* (on ENST00000323669; = p.E301* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100080185; called by muse, mutect2, varscan2
- DDX43 | c.1406C>A p.T469N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV100944084; called by muse, mutect2, varscan2
- DIAPH2 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV100235698; called by muse, mutect2, varscan2
- DLK1 | c.482G>C p.G161A | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100375492; called by muse, mutect2, varscan2
- DNAH7 | c.2063G>T p.R688L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100418030, COSV56774077; called by muse, mutect2, varscan2
- EDA2R | c.125C>G p.T42R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV99491040; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668905; called by muse, mutect2, varscan2
- EFR3A | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99603703; called by muse, mutect2
- EGFL6 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs778515412, COSV100768721; called by muse, mutect2, varscan2
- EPHA2 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs768552046, COSV64453706; called by muse, mutect2
- EPHA3 | c.679A>T p.R227* | Nonsense Mutation (SNP) | VAF 42/202 reads (21%) | catalogued as COSV100349364; called by muse, mutect2, varscan2
- EPHA6 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101065934; called by muse, mutect2, varscan2
- EPHA7 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV100992557; called by muse, mutect2, varscan2
- EPHB1 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101214657; called by muse, mutect2, varscan2
- FAM135B | c.3145A>T p.K1049* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV99428293; called by muse, mutect2, varscan2
- FAM135B | c.2948G>T p.G983V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99428295; called by muse, mutect2, varscan2
- FAR2 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99479692; called by muse, mutect2, varscan2
- FBXO30 | c.1445C>A p.A482D | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99395466; called by muse, mutect2
- FGD4 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691854, COSV56789953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXN4 | c.799del p.L267Cfs*4 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV54494764; called by mutect2, pindel, varscan2
- FREM2 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV54843455, COSV99751368; called by muse, mutect2, varscan2
- FTSJ1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191461; called by muse, mutect2, varscan2
- GAD2 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs950190434, COSV99394181; called by muse, mutect2, varscan2
- GAD2 | c.1669T>A p.F557I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV99392398, COSV99394183; called by muse, mutect2, varscan2
- GPD2 | c.102+1G>A p.X34_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as rs1263693385, COSV100133726; called by mutect2, varscan2
- GPR34 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100587850; called by muse, mutect2, varscan2
- GPRASP1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV100851093; called by muse, mutect2, varscan2
- GRIA1 | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602722; called by muse, mutect2, varscan2
- GRIA1 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99602726; called by muse, mutect2, varscan2
- GRIK2 | c.2400G>T p.R800S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV100029879; called by muse, mutect2, varscan2
- GRM3 | c.1873T>A p.S625T | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV100862970; called by muse, mutect2, varscan2
- H4C3 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100619673; called by muse, mutect2, varscan2
- HACD1 | c.818A>C p.Q273P | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100778520; called by muse, mutect2, varscan2
- HDC | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.231); catalogued as COSV99984364; called by muse, mutect2, varscan2
- HMGXB4 | c.242A>T p.D81V | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99330296; called by muse, mutect2, varscan2
- HTN1 | c.116C>G p.S39* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99887604; called by muse, mutect2, varscan2
- ICE1 | c.6393G>C p.W2131C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99665911; called by muse, mutect2
- IQUB | c.2272C>A p.L758M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.289); catalogued as COSV100227409; called by muse, mutect2, varscan2
- ITGAD | c.1436C>G p.A479G | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV101210607; called by muse, mutect2, varscan2
- KCNH6 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 89/131 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.262); catalogued as COSV100121297; called by muse, mutect2, varscan2
- KCNH7 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100150162, COSV59804311; called by muse, mutect2, varscan2
- KIAA1549 | c.2411T>C p.L804S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV99652274; called by muse, mutect2
- KIF5C | c.2831G>C p.G944A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101276220; called by muse, mutect2, varscan2
- KIZ | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as COSV99852461; called by muse, mutect2, varscan2
- KRT26 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.513); catalogued as rs774474058, COSV56970604; called by muse, mutect2, varscan2
- KRTAP13-1 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV100819952, COSV62664264; called by muse, mutect2, varscan2
- LAMB1 | c.4408C>A p.L1470M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99741828; called by muse, mutect2, varscan2
- LIG1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372831646; called by muse, mutect2, varscan2
- LILRB1 | c.190A>C p.K64Q (on ENST00000427581; = p.K28Q on NM_006669.6) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100208004; called by muse, mutect2, varscan2
- LMBRD2 | c.1283A>G p.Y428C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99683318; called by muse, mutect2
- LRFN4 | c.1313A>C p.Q438P | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100540913; called by muse, mutect2, varscan2
- LRRC66 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100603123; called by muse, mutect2, varscan2
- MAGEB18 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100305660, COSV57463393; called by muse, mutect2, varscan2
- MAGEC1 | c.3286C>A p.P1096T | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53572893, COSV99596718; called by muse, mutect2, varscan2
- MAGEC2 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.408); catalogued as COSV99910000; called by muse, mutect2, varscan2
- MAP3K5 | c.34T>A p.S12T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as COSV100753365; called by muse, mutect2
- MAPK1 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99308248; called by muse, mutect2, varscan2
- MED13 | c.4211A>G p.H1404R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV67267673; called by muse, mutect2, varscan2
- MED14 | c.2544C>A p.H848Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100247671; called by muse, mutect2
- MIA2 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99698313; called by muse, mutect2, varscan2
- MIS18BP1 | c.1500C>A p.D500E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100173316; called by muse, mutect2, varscan2
- MROH2B | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV101270957; called by muse, mutect2, varscan2
- MYH4 | c.4768C>A p.L1590I | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99702434; called by muse, mutect2, varscan2
- MYO16 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194808; called by muse, mutect2, varscan2
- MYO9A | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100614513; called by muse, mutect2, varscan2
- NAV2 | c.3079C>T p.P1027S (on ENST00000396087 / NM_001244963.2; = p.P1004S on NM_145117.5) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100217746; called by muse, mutect2, varscan2
- NDRG2 | c.325G>T p.A109S (on ENST00000298687 / NM_001354570.1; = p.A95S on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100069183; called by muse, mutect2, varscan2
- NDUFA4L2 | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100197465; called by muse, mutect2, varscan2
- NEB | c.6236G>T p.R2079L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760134969, COSV50808106, COSV99428653; called by muse, mutect2, varscan2
- NFX1 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs755754909, COSV101076987; called by muse, varscan2
- NIPBL | c.7900G>A p.E2634K | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99243018; called by muse, mutect2, varscan2
- NLRP13 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100738604; called by muse, mutect2, varscan2
- NRDC | c.3527C>A p.S1176Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100544160; called by muse, mutect2, varscan2
- NRIP1 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100013186; called by muse, mutect2, varscan2
- NTN5 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV99539621; called by muse, mutect2, varscan2
- OAF | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0); catalogued as COSV100203011; called by muse, mutect2, varscan2
- OR10G8 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV101461889, COSV70908370; called by muse, mutect2, varscan2
- OR14K1 | c.560G>C p.C187S | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV99315534; called by muse, mutect2, varscan2
- OR2G2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs760303730, COSV100190044; called by muse, mutect2, varscan2
- OR2L3 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100742071, COSV63455473; called by muse, varscan2
- OR2T10 | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV100393835; called by muse, mutect2, varscan2
- OR4Q3 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV59178583; called by muse, mutect2, varscan2
- OR5D16 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as COSV101004163; called by muse, mutect2, varscan2
- OR5D18 | c.621T>A p.N207K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100450928; called by muse, mutect2, varscan2
- OR5H15 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368306904; called by muse, mutect2, varscan2
- OR5M10 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV101595926; called by muse, mutect2, varscan2
- OR5M8 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100510805, COSV59116763; called by muse, mutect2, varscan2
- OR8J1 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); catalogued as COSV100275271, COSV57318936; called by muse, mutect2, varscan2
- OR8K5 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100537360; called by muse, mutect2
- PCDH11X | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015835, COSV53509311; called by muse, mutect2, varscan2
- PCDHA4 | c.1748G>T p.W583L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100793809, COSV63542735; called by muse, varscan2
- PCDHA5 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65351686; called by muse, mutect2, varscan2
- PCF11 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100019367, COSV53533523; called by muse, mutect2, varscan2
- PCLO | c.11563C>G p.R3855G | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444173167, COSV100438834, COSV61655334; called by muse, mutect2, varscan2
- PCLO | c.10051G>C p.A3351P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100438838; called by muse, mutect2, varscan2
- PDE3B | c.1435G>T p.G479W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99963411; called by muse, mutect2, varscan2
- PDE3B | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99963415, COSV99963532; called by muse, mutect2, varscan2
- PLAC1 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV100821676; called by muse, mutect2, varscan2
- PLD1 | c.3095G>C p.R1032P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.669); catalogued as COSV100643960, COSV100644101; called by muse, mutect2, varscan2
- PLEC | c.11479G>T p.G3827C (on ENST00000322810 / NM_201380.4; = p.G3717C on NM_000445.5) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519740; called by muse, mutect2, varscan2
- PLEKHA5 | c.2628G>C p.M876I | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762589285, COSV100164848; called by muse, mutect2, varscan2
- PLEKHO2 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs759474291, COSV100061018; called by muse, mutect2, varscan2
- PLXNA4 | c.5248A>T p.N1750Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100327685; called by muse, mutect2, varscan2
- POLN | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101242855; called by muse, mutect2, varscan2
- POLR3B | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99943933; called by muse, mutect2, varscan2
- PORCN | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100400585; called by muse, mutect2, varscan2
- PRKD1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV100121739; called by muse, mutect2, varscan2
- PSD4 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as rs1035677270, COSV55526653; called by muse, mutect2, varscan2
- PTPRC | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100723281; called by muse, mutect2, varscan2
- PTPRE | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV99619191; called by muse, mutect2, varscan2
- PTPRH | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs112913803, COSV54751432; called by muse, mutect2, varscan2
- PTPRM | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV100161034; called by muse, mutect2, varscan2
- PTPRS | c.2371G>T p.E791* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99512740; called by muse, mutect2, varscan2
- RAG2 | c.806A>T p.D269V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV100271541; called by muse, mutect2, varscan2
- RBCK1 | c.370G>T p.D124Y (on ENST00000356286 / NM_031229.4; = p.D82Y on NM_006462.6) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV100676008; called by muse, mutect2, varscan2
- RETSAT | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs370464576, COSV55525646; called by muse, mutect2, varscan2
- RIMBP2 | c.2911A>G p.N971D | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99900761; called by muse, mutect2, varscan2
- RUNX1T1 | c.1281del p.D427Efs*30 (on ENST00000265814 / NM_001198628.1; = p.D400Efs*30 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | catalogued as COSV56160627; called by mutect2, pindel, varscan2
- RXFP4 | c.1096A>C p.T366P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as COSV100563492; called by muse, mutect2, varscan2
- RYR2 | c.13597C>T p.L4533F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs760283753, COSV100773182; called by muse, varscan2
- SATL1 | c.620C>G p.P207R (on ENST00000395409; = p.P394R on NM_001012980.2) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV100261129; called by muse, mutect2, varscan2
- SEC22A | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100007156; called by muse, mutect2, varscan2
- SEC63 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100938488; called by muse, mutect2, varscan2
- SGCD | c.193G>T p.G65* (on ENST00000435422 / NM_001128209.2; = p.G66* on NM_000337.5) | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100551336; called by muse, mutect2, varscan2
- SGCD | c.194G>T p.G65V (on ENST00000435422 / NM_001128209.2; = p.G66V on NM_000337.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550074, COSV100551337; called by muse, mutect2, varscan2
- SH3BP4 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs750574031, COSV100749355; called by muse, mutect2, varscan2
- SHE | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as COSV100496244; called by muse, mutect2, varscan2
- SLC12A9 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.407); catalogued as COSV51933116, COSV99308277; called by muse, mutect2, varscan2
- SLC17A6 | c.1360A>G p.T454A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99582515; called by muse, mutect2, varscan2
- SLC4A3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs387907531, COSV99813346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLFNL1 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100263199; called by muse, mutect2, varscan2
- SLITRK3 | c.2534G>T p.G845V | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.994); catalogued as COSV53849171, COSV53854655; called by muse, mutect2, varscan2
- SPAG6 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100510569, COSV57617859; called by muse, mutect2, varscan2
- SPTA1 | c.7165G>T p.A2389S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV100779099; called by muse, mutect2, varscan2
- SRRT | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs979617228, COSV100730408; called by muse, mutect2, varscan2
- STAG2 | c.2526T>A p.N842K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.028); catalogued as COSV99495655; called by muse, mutect2
- STX16 | c.460G>T p.E154* (on ENST00000371141 / NM_001001433.3; = p.E133* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100397673, COSV56608776; called by muse, mutect2, varscan2
- TAF1 | c.5496C>A p.D1832E (on ENST00000373790 / NM_138923.4; = p.D1853E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV52118750, COSV99337219; called by muse, mutect2, varscan2
- TARS1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 131/181 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs931088234, COSV99466557; called by muse, mutect2, varscan2
- TBX22 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100960972; called by muse, mutect2, varscan2
- THEMIS2 | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100198182; called by muse, mutect2, varscan2
- THEMIS2 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100198183; called by muse, mutect2, varscan2
- THOC2 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99833705; called by muse, mutect2, varscan2
- TLE4 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54642295, COSV99513399; called by muse, mutect2, varscan2
- TLN2 | c.3811G>A p.A1271T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.044); catalogued as COSV100170258; called by muse, mutect2, varscan2
- TMEM74 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99865987; called by muse, mutect2, varscan2
- TPTE | c.1315A>G p.K439E (on ENST00000618007 / NM_199261.4; = p.K421E on NM_199259.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1299965815; called by muse, mutect2
- TTC38 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 50/93 reads (54%) | catalogued as COSV101123953; called by muse, mutect2, varscan2
- TTLL10 | c.1089-1G>T p.X363_splice (on ENST00000379289 / NM_001130045.2; = p.X290_splice on NM_153254.3) | Splice Site (SNP) | VAF 21/155 reads (14%) | catalogued as COSV101016981; called by muse, mutect2, varscan2
- TTN | c.81359G>A p.R27120K (on ENST00000591111; = p.R19696K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/125 reads (36%) | PolyPhen benign (0.003); catalogued as COSV100633528; called by muse, mutect2, varscan2
- TTN | c.6355G>A p.E2119K (on ENST00000591111; = p.E2073K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | PolyPhen probably damaging (0.994); catalogued as CM1514658, COSV100591218; called by muse, mutect2, varscan2
- TUSC3 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101142917, COSV65886145; called by muse, mutect2, varscan2
- TWNK | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99273297; called by muse, mutect2, varscan2
- UGT3A1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99955426; called by muse, mutect2, varscan2
- UGT3A2 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99236914; called by muse, mutect2, varscan2
- UGT3A2 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 110/158 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99236916; called by muse, mutect2, varscan2
- USP51 | c.513C>G p.D171E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.012); catalogued as COSV101540705, COSV72351923; called by muse, mutect2, varscan2
- VIRMA | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.316); catalogued as COSV99889673; called by muse, mutect2
- VIRMA | c.351T>A p.Y117* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99889676; called by muse, mutect2
- WDFY1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1258150482, COSV99239949; called by muse, mutect2, varscan2
- WHRN | c.792C>G p.D264E | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54334329; called by muse, mutect2, varscan2
- YIPF6 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV101006287; called by muse, mutect2, varscan2
- ZBTB9 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV101221815; called by muse, mutect2, varscan2
- ZCCHC24 | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100959518, COSV64887304; called by muse, mutect2
- ZDBF2 | c.5257G>T p.A1753S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100985642; called by muse, mutect2, varscan2
- ZFP37 | c.1826C>G p.T609S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100953358, COSV65289015; called by muse, mutect2, varscan2
- ZIC4 | c.394T>G p.W132G | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268187; called by muse, mutect2, varscan2
- ZMYM3 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100078465; called by muse, mutect2, varscan2
- ZNF267 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1410316513, COSV100339957; called by muse, mutect2, varscan2
- ZNF48 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755793843, COSV60782685; called by muse, mutect2, varscan2
- ZNF493 | c.1898T>C p.I633T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100828987; called by muse, mutect2, varscan2
- ZNF687 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99650272; called by muse, mutect2, varscan2
- ZNF804A | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100165918; called by muse, mutect2, varscan2
- ZNF804B | c.1118A>T p.Y373F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV100306646; called by muse, mutect2, varscan2
- ZPLD1 | c.1007C>T p.A336V (on ENST00000466937 / NM_001329788.1; = p.A352V on NM_175056.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as rs776042081, COSV100083620; called by muse, mutect2, varscan2
- ATP10B | c.2922dup p.G975Wfs*81 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by pindel, varscan2
- B4GALNT4 | c.872_904del p.D291_S302delinsG | In Frame Del (DEL) | VAF 24/85 reads (28%) | called by mutect2, pindel
- MED15 | c.1841dup p.Q615Afs*53 (on ENST00000263205 / NM_001003891.3; = p.Q575Afs*53 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 45/402 reads (11%) | called by mutect2, pindel, varscan2
- RABEP2 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- RTP3 | c.73_74del p.W25Dfs*36 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- SLC22A6 | c.558del p.I187Sfs*21 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- TAF9B | c.385del p.L129* | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- TRBV29-1 | c.126C>G p.S42R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ACKR1 | c.939C>A p.R313= | Silent (SNP) | VAF 60/369 reads (16%) | catalogued as COSV100929692; called by muse, mutect2, varscan2
- ANKS1B | c.1848T>C p.C616= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV100248594; called by muse, mutect2, varscan2
- ARVCF | c.1674G>A p.V558= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs1569156891, COSV99599577; called by muse, mutect2, varscan2
- BCORL1 | c.1269T>G p.P423= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV99501168; called by muse, mutect2, varscan2
- C2CD5 | c.312C>A p.V104= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100449108; called by muse, mutect2, varscan2
- CD33 | c.669G>C p.T223= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99220855; called by muse, mutect2, varscan2
- CD82 | c.480C>T p.D160= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as rs1275071733, COSV99907866; called by muse, mutect2, varscan2
- CNTN4 | c.618G>T p.L206= | Silent (SNP) | VAF 37/49 reads (76%) | catalogued as COSV100638794; called by muse, mutect2, varscan2
- CSMD1 | c.2055G>T p.G685= (on ENST00000520002; = p.G684= on NM_033225.6) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs755136474, COSV100154585; called by muse, mutect2, varscan2
- DENND2A | c.615G>C p.L205= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99327112; called by muse, mutect2, varscan2
- ERBB4 | c.468T>C p.C156= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99634783; called by mutect2, varscan2
- ESRP1 | c.354G>T p.L118= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100619715; called by muse, mutect2, varscan2
- GRM3 | c.807G>A p.A269= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs190728505; called by muse, mutect2, varscan2
- HEXA | c.66C>G p.A22= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV99173861; called by muse, mutect2, varscan2
- INSC | c.462C>T p.S154= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1238626126, COSV65410328; called by muse, mutect2
- KCNJ8 | c.792T>G p.P264= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99557751; called by muse, mutect2, varscan2
- KIAA1210 | c.1533G>A p.K511= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV101274439; called by muse, mutect2, varscan2
- MAG | c.1626G>A p.V542= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1568477391, COSV100728098; called by muse, varscan2
- MYH1 | c.2601G>T p.L867= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99877065; called by muse, mutect2, varscan2
- MYLK4 | c.912G>T p.L304= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV99193926; called by muse, mutect2, varscan2
- NFATC2IP | c.1140G>A p.E380= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV100297653; called by muse, mutect2, varscan2
- NLGN4X | c.174A>G p.L58= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV99324305; called by muse, mutect2, varscan2
- NLRP13 | c.2904A>T p.G968= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV100738603; called by muse, mutect2, varscan2
- OR8K3 | c.357C>A p.S119= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100449924; called by muse, mutect2
- OTOP1 | c.1056G>A p.L352= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV99588234; called by muse, mutect2, varscan2
- OVCH1 | c.3141A>T p.P1047= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV100549308; called by muse, mutect2, varscan2
- PCDHA4 | c.1437G>T p.A479= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100793393, COSV100793807; called by muse, mutect2, varscan2
- PCDHAC2 | c.1638T>C p.F546= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99163450; called by muse, mutect2, varscan2
- PKHD1 | c.2341C>A p.R781= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as CM051135, COSV100584810, COSV61864770; called by muse, mutect2, varscan2
- PLEC | c.11478G>T p.T3826= (on ENST00000322810 / NM_201380.4; = p.T3716= on NM_000445.5) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100519742, COSV59680962; called by muse, mutect2, varscan2
- PPP2R3B | c.501G>C p.L167= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV101065617; called by muse, mutect2, varscan2
- PROX1 | c.928C>A p.R310= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs762987208, COSV54782584, COSV99800338; called by muse, mutect2, varscan2
- PTCHD4 | c.2022G>C p.L674= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs758403554, COSV100261855; called by muse, mutect2, varscan2
- SCRT1 | c.675G>T p.P225= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100146557; called by muse, mutect2, varscan2
- SCTR | c.495T>C p.C165= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99191772; called by muse, mutect2, varscan2
- SGF29 | c.114C>T p.I38= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs557657718, COSV100397092; called by muse, mutect2, varscan2
- SLC25A43 | c.339G>C p.G113= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV99474627, COSV99474805; called by muse, mutect2, varscan2
- SLC9C2 | c.207C>T p.H69= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100877036; called by muse, mutect2, varscan2
- SP100 | c.39G>T p.L13= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99894429; called by muse, mutect2, varscan2
- SULF1 | c.1104C>A p.I368= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as COSV99484510; called by muse, mutect2, varscan2
- TCEAL1 | c.132G>T p.S44= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101010138; called by muse, mutect2, varscan2
- TDRD6 | c.534C>T p.R178= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as rs1452249114, COSV100288462; called by muse, mutect2, varscan2
- TENM1 | c.7707G>T p.G2569= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100951180; called by muse, mutect2, varscan2
- TGM5 | c.255C>A p.P85= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as CD152141, COSV99589385; called by muse, mutect2, varscan2
- TMEM74 | c.375G>T p.R125= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV99865990; called by muse, mutect2, varscan2
- TNN | c.3753C>T p.H1251= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99513236; called by muse, mutect2
- UTRN | c.4209G>T p.L1403= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100840720; called by muse, mutect2, varscan2
- WNT1 | c.666G>C p.G222= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99525370; called by muse, mutect2, varscan2
- ZNF208 | c.3327A>T p.G1109= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1334220572, COSV101237249; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825897 A>C | 5'Flank (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- AL353804.6 | chrX:73826510 T>A | 3'Flank (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- DEFB119 | c.62-935G>A | Intron (SNP) | VAF 14/253 reads (6%) | catalogued as COSV53621205; called by muse, mutect2
- MIR1269A | n.38C>A | RNA (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2
- OR2W5 | n.417C>G | RNA (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- OR2W5 | n.550C>A | RNA (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- XIST | n.7253T>A | RNA (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
